Somatic mutation profile of tumor specimen TCGA-22-5473-01A (aliquot TCGA-22-5473-01A-01D-1632-08) from TCGA case TCGA-22-5473, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 78.9 years (28,826 days).
Specimen TCGA-22-5473-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb037d09-94d7-4bb8-9dde-90c59c5dd9c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5473-11A (Solid Tissue Normal), aliquot TCGA-22-5473-11A-11D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac0c1f4d-41e6-4ced-8686-353c2830e0a0

The open-access MAF lists 876 somatic variants for this specimen: 621 protein-altering or splice-affecting, 233 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 531, Silent 233, Nonsense Mutation 45, Frame Shift Del 18, Splice Site 17, RNA 9, Intron 7, Splice Region 5, Frame Shift Ins 4, 3'Flank 2, 5'UTR 2, Nonstop Mutation 1.

Variants (750 of 876; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.73-1G>A p.X25_splice | Splice Site (SNP) | VAF 27/155 reads (17%) | catalogued as rs1555054043, COSV53771537, COSV99592353; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GBA | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs78973108, CM940809; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.77A>C p.Q26P | Missense Mutation (SNP) | VAF 17/97 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101229454, COSV67961584, COSV67961602; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 83/220 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 51/103 reads (50%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.860A>T p.H287L | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61788034; called by muse, mutect2, varscan2
- ABCA10 | c.2497+1G>A p.X833_splice | Splice Site (SNP) | VAF 32/96 reads (33%) | catalogued as COSV52227753, COSV52229109; called by muse, mutect2, varscan2
- ABCA13 | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 91/122 reads (75%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as COSV101330044, COSV70042618; called by muse, mutect2, varscan2
- ABCA4 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV64672104; called by muse, mutect2, varscan2
- ABCA5 | c.870A>T p.L290F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as COSV67018888; called by muse, mutect2, varscan2
- ABCB11 | c.1127C>G p.A376G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55599939; called by muse, mutect2, varscan2
- ABCC2 | c.2368G>T p.A790S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1239835776, COSV64988392; called by muse, mutect2, varscan2
- ABCG5 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV53213281; called by muse, mutect2, varscan2
- AC011455.2 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 33/196 reads (17%) | catalogued as COSV55501510; called by muse, mutect2, varscan2
- ACADVL | c.470A>T p.N157I | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50039462; called by muse, mutect2, varscan2
- ACKR3 | c.47A>T p.D16V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV56023480; called by muse, mutect2, varscan2
- ACSM2A | c.674G>T p.S225I (on ENST00000219054; = p.S146I on NM_001308169.2) | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV54589067; called by muse, mutect2, varscan2
- ACTG2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs771147501, COSV61827351, COSV61829531; called by muse, mutect2, varscan2
- ACTL8 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1182735417, COSV64862601; called by muse, mutect2, varscan2
- ACVRL1 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.07); catalogued as COSV66360974; called by muse, mutect2, varscan2
- ADAMTS12 | c.2071T>A p.C691S | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61277258; called by muse, mutect2, varscan2
- ADCY2 | c.1671G>C p.M557I | Missense Mutation (SNP) | VAF 24/315 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV57897058; called by muse, mutect2
- ADCY5 | c.1892A>T p.Y631F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as COSV59203703; called by muse, mutect2, varscan2
- ADGRB1 | c.1428G>T p.W476C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60102892; called by muse, mutect2, varscan2
- ADGRL2 | c.2640T>A p.N880K (on ENST00000370717 / NM_001366005.1; = p.N867K on NM_012302.4) | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54678769, COSV54686594; called by muse, mutect2, varscan2
- ADGRL4 | c.1461+1G>T p.X487_splice | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV66065413; called by muse, varscan2
- ADGRV1 | c.18890G>T p.R6297M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV67994331; called by muse, mutect2, varscan2
- AGO3 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV55796714, COSV55797734; called by muse, mutect2, varscan2
- AHCTF1 | c.5825G>C p.R1942T (on ENST00000366508; = p.R1916T on NM_015446.5) | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV58254682; called by muse, mutect2, varscan2
- AKAP6 | c.5878C>T p.L1960F | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as COSV55231084; called by muse, mutect2
- ALCAM | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60254211; called by muse, mutect2, varscan2
- ALDH8A1 | c.1084A>T p.S362C | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.684); catalogued as COSV55644108; called by muse, mutect2, varscan2
- ALMS1 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV52520772; called by muse, mutect2, varscan2
- ALS2 | c.4657G>A p.A1553T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.243); catalogued as rs1036920333, COSV51892015; called by muse, mutect2, varscan2
- AMER3 | c.1836G>T p.L612F | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV58469742; called by muse, mutect2, varscan2
- ANAPC13 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61566308; called by muse, mutect2, varscan2
- ANK3 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55079218; called by muse, mutect2, varscan2
- ANKRA2 | c.739-1G>A p.X247_splice | Splice Site (SNP) | VAF 6/78 reads (8%) | catalogued as COSV57141725; called by muse, mutect2
- ANKRD12 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV50830476, COSV50844927; called by muse, mutect2, varscan2
- ANKRD27 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV60135598; called by muse, mutect2, varscan2
- ANO3 | c.2248G>T p.G750* | Nonsense Mutation (SNP) | VAF 77/111 reads (69%) | catalogued as COSV56807013; called by muse, mutect2, varscan2
- ANO4 | c.2042G>A p.R681Q (on ENST00000392977 / NM_001286615.2; = p.R646Q on NM_178826.4) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as rs774283498, COSV54603606; called by muse, mutect2, varscan2
- ANO9 | c.1188C>T p.I396= | Splice Region (SNP) | VAF 15/58 reads (26%) | catalogued as COSV60451637; called by muse, mutect2, varscan2
- AOAH | c.1216del p.H406Tfs*33 | Frame Shift Del (DEL) | VAF 54/96 reads (56%) | catalogued as COSV51741654; called by mutect2, pindel, varscan2
- AOX1 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65983750; called by muse, mutect2, varscan2
- AP1S3 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458912987, COSV57512764; called by muse, mutect2, varscan2
- APBA2 | c.1418G>C p.R473P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67105630; called by muse, mutect2, varscan2
- APOB | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs548108916, CD096704, COSV51939155; called by muse, mutect2, varscan2
- ARHGAP31 | c.3023G>C p.R1008T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV51798305; called by muse, mutect2, varscan2
- ARHGAP33 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs202034847, COSV50156416; called by muse, mutect2, varscan2
- ARHGAP35 | c.3991C>T p.P1331S | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV68335388; called by muse, mutect2, varscan2
- ARID2 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57609210, COSV57613546; called by muse, mutect2, varscan2
- ARID2 | c.3044A>C p.Q1015P | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV57613557; called by muse, mutect2, varscan2
- ARID5B | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV54428834; called by muse, mutect2, varscan2
- ARR3 | c.212T>A p.F71Y | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57205288; called by muse, mutect2, varscan2
- ASCC2 | c.1809G>C p.E603D | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57076370; called by muse, varscan2
- ASNSD1 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 65/301 reads (22%) | catalogued as COSV53624816, COSV99641055; called by muse, mutect2, varscan2
- ASPDH | c.463G>A p.D155N (on ENST00000389208 / NM_001114598.2; = p.D50N on NM_001024656.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs1431809948, COSV65350029; called by muse, mutect2, varscan2
- ASPM | c.9526G>C p.E3176Q | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV54128692, COSV54137736; called by muse, mutect2, varscan2
- ATG2A | c.1859T>G p.L620R | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV65968716; called by muse, mutect2, varscan2
- ATP10A | c.3266T>C p.V1089A | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV63523327; called by muse, mutect2, varscan2
- ATP10A | c.2247G>A p.M749I | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63523334; called by muse, mutect2, varscan2
- ATP13A3 | c.3037C>G p.Q1013E | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as COSV55469138; called by muse, mutect2
- ATP2A1 | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62870817; called by muse, mutect2, varscan2
- ATP6V1H | c.1216G>C p.V406L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV62220148; called by muse, mutect2, varscan2
- ATP8A2 | c.1662+1G>A p.X554_splice | Splice Site (SNP) | VAF 51/133 reads (38%) | catalogued as COSV54974895; called by muse, mutect2, varscan2
- AUTS2 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV61384387, COSV61427591; called by muse, mutect2, varscan2
- BEND2 | c.1034-2A>T p.X345_splice | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as COSV66217092; called by muse, mutect2, varscan2
- BEND2 | c.437G>C p.S146T | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV66217094; called by muse, mutect2, varscan2
- BPTF | c.5972G>T p.S1991I | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58845822; called by muse, mutect2, varscan2
- BRINP1 | c.155G>T p.R52M | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV56312023; called by muse, mutect2, varscan2
- BRWD3 | c.1939C>G p.L647V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV64744132, COSV64753055; called by muse, mutect2, varscan2
- BTD | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs1460015822, COSV57730410; called by muse, mutect2, varscan2
- C8orf76 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 34/159 reads (21%) | catalogued as rs980902405, COSV52691835; called by muse, varscan2
- C9orf40 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV65228765; called by muse, mutect2, varscan2
- CA3 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53411246; called by muse, mutect2, varscan2
- CACNA2D1 | c.2563G>A p.D855N (on ENST00000356253 / NM_001366867.1; = p.D843N on NM_000722.4) | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV62387228; called by muse, mutect2, varscan2
- CACNA2D4 | c.2532G>C p.K844N | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs369000289, COSV54566588; called by muse, mutect2, varscan2
- CAD | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 93/546 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV53031320; called by muse, mutect2, varscan2
- CAPN3 | c.1628T>G p.V543G | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV58825965; called by muse, varscan2
- CAPRIN2 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51835203; called by muse, mutect2, varscan2
- CASD1 | c.1476+1G>T p.X492_splice | Splice Site (SNP) | VAF 103/265 reads (39%) | catalogued as COSV51975169; called by muse, mutect2, varscan2
- CASP5 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as COSV52831453; called by muse, mutect2, varscan2
- CCDC7 | c.3171G>C p.K1057N | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56551020; called by muse, mutect2, varscan2
- CCDC73 | c.917A>T p.K306M | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58804147; called by muse, mutect2, varscan2
- CCDC74A | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369824578; called by muse, mutect2, varscan2
- CCDC9B | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66876176; called by muse, mutect2, varscan2
- CCNO | c.502A>T p.T168S | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV57005114; called by muse, mutect2, varscan2
- CCR1 | c.35C>A p.T12K | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT tolerated (0.87); PolyPhen benign (0.018); catalogued as COSV56122925; called by muse, mutect2, varscan2
- CD1C | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 346/510 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100939417, COSV63806287; called by mutect2, varscan2
- CD207 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 23/137 reads (17%) | catalogued as COSV69652554; called by muse, mutect2, varscan2
- CD5L | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV100940993, COSV63822990; called by muse, mutect2, varscan2
- CDC42BPA | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62002238; called by muse, mutect2
- CDH18 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 87/148 reads (59%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.978); catalogued as COSV56956853; called by muse, mutect2, varscan2
- CDH23 | c.5396G>A p.G1799E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56486733; called by muse, mutect2, varscan2
- CDH9 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 304/578 reads (53%) | catalogued as COSV50419019; called by muse, mutect2, varscan2
- CDK8 | c.934-2A>C p.X312_splice | Splice Site (SNP) | VAF 52/178 reads (29%) | catalogued as COSV67422931; called by muse, mutect2, varscan2
- CELF4 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100611518, COSV58464883; called by muse, mutect2, varscan2
- CEP126 | c.1600A>G p.K534E | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.22); catalogued as COSV54830106; called by muse, mutect2, varscan2
- CEP152 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57864326; called by muse, mutect2, varscan2
- CEP350 | c.6159G>T p.R2053S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62609081; called by muse, mutect2, varscan2
- CEP85 | c.2039G>C p.C680S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53332269; called by muse, mutect2, varscan2
- CFTR | c.165-1G>T p.X55_splice | Splice Site (SNP) | VAF 77/205 reads (38%) | catalogued as CS000849, COSV50092865; called by muse, mutect2, varscan2
- CHD9 | c.8224A>T p.K2742* (on ENST00000398510 / NM_001382353.1; = p.K2726* on NM_025134.7) | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV54615625, COSV54619104; called by muse, mutect2, varscan2
- CHUK | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 44/160 reads (28%) | catalogued as COSV64918653; called by muse, mutect2, varscan2
- CLEC4C | c.639A>G p.I213M | Missense Mutation (SNP) | VAF 134/204 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs147980423; called by muse, mutect2, varscan2
- CLRN1 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV58996675; called by muse, mutect2, varscan2
- CLSTN2 | c.1882C>A p.L628I | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV71724572; called by muse, mutect2, varscan2
- CLVS2 | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.682); catalogued as COSV51568491; called by muse, mutect2, varscan2
- CLVS2 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.167); catalogued as COSV51568505, COSV99253847; called by muse, varscan2
- CLVS2 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51568515; called by muse, varscan2
- CNTNAP2 | c.1205G>T p.R402M | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62248689, COSV62267885; called by muse, mutect2, varscan2
- CNTNAP5 | c.2663T>A p.L888Q | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445570473, COSV70509698; called by muse, mutect2, varscan2
- COL19A1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV59586783; called by muse, mutect2, varscan2
- COL5A2 | c.4325G>C p.R1442P | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV66414520; called by muse, mutect2, varscan2
- COL6A2 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100154215, COSV56015166; called by muse, mutect2, varscan2
- COL7A1 | c.7534A>G p.S2512G | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV60402347; called by muse, mutect2, varscan2
- COL9A1 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57892291; called by muse, mutect2, varscan2
- COLGALT1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.506); catalogued as rs761108171, COSV53107474; called by muse, mutect2, varscan2
- COPS7B | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62601599; called by muse, mutect2, varscan2
- CPAMD8 | c.4867G>T p.V1623L (on ENST00000651564; = p.V1576L on NM_015692.5) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV71597329; called by muse, mutect2, varscan2
- CPN1 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs775824980, COSV64941987; called by muse, mutect2, varscan2
- CROT | c.1839G>C p.*613Yext*2 | Nonstop Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as COSV55941137; called by muse, mutect2, varscan2
- CSGALNACT2 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV65676331; called by muse, mutect2, varscan2
- CSMD1 | c.6047A>T p.Q2016L (on ENST00000520002; = p.Q2015L on NM_033225.6) | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59376989; called by muse, mutect2, varscan2
- CSMD3 | c.4813C>G p.P1605A (on ENST00000297405 / NM_001363185.1; = p.P1501A on NM_052900.3) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52210269, COSV52303554; called by muse, mutect2, varscan2
- CSMD3 | c.4812C>A p.F1604L (on ENST00000297405 / NM_001363185.1; = p.F1500L on NM_052900.3) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV52184427, COSV52303576; called by muse, mutect2, varscan2
- CSMD3 | c.4246G>T p.G1416C (on ENST00000297405 / NM_001363185.1; = p.G1312C on NM_052900.3) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52303596; called by muse, mutect2, varscan2
- CWC22 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs779850018, COSV55432046; called by muse, mutect2, varscan2
- CYLD | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 86/148 reads (58%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.186); catalogued as COSV61097174; called by muse, mutect2, varscan2
- CYP2F1 | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV58528704; called by muse, mutect2, varscan2
- CYTH4 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50635532; called by muse, mutect2, varscan2
- DALRD3 | c.589G>C p.E197Q (on ENST00000341949 / NM_001009996.3; = p.E30Q on NM_018114.5) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV58243990, COSV58247280; called by muse, mutect2, varscan2
- DDX60L | c.2324C>A p.S775Y | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52721021; called by muse, mutect2
- DENND4A | c.424A>C p.I142L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as COSV71266922; called by muse, mutect2, varscan2
- DHX34 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs775749081, COSV60894800; called by muse, mutect2, varscan2
- DMXL2 | c.3376G>A p.D1126N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51843910; called by muse, mutect2, varscan2
- DNAH1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.935); catalogued as COSV70235495; called by muse, mutect2, varscan2
- DNAH10 | c.3797G>T p.G1266V (on ENST00000409039; = p.G1205V on NM_207437.3) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69000380; called by muse, mutect2
- DNAH12 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV60858597; called by muse, mutect2, varscan2
- DNAH5 | c.11740G>A p.E3914K | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV54249030; called by muse, mutect2, varscan2
- DNAH7 | c.10219C>A p.R3407S | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV56783351; called by muse, mutect2, varscan2
- DOCK10 | c.2395C>G p.Q799E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs746523802, COSV51426203; called by muse, mutect2, varscan2
- DPH6 | c.24-2A>T p.X8_splice | Splice Site (SNP) | VAF 64/258 reads (25%) | catalogued as COSV56619064; called by muse, mutect2, varscan2
- DPYD | c.2112T>G p.I704M | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV64613070; called by muse, mutect2, varscan2
- DPYD | c.1339+1G>C p.X447_splice | Splice Site (SNP) | VAF 46/169 reads (27%) | catalogued as CS052409, COSV64613072; called by muse, mutect2, varscan2
- DPYD | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV64615647; called by muse, mutect2, varscan2
- DPYS | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60910523, COSV60911537; called by muse, mutect2, varscan2
- DYNC2H1 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 159/259 reads (61%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs1301978864, COSV62105560; called by muse, mutect2, varscan2
- DYNC2H1 | c.3492G>A p.M1164I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62105566; called by muse, mutect2, varscan2
- DYNC2I1 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV68106905; called by muse, mutect2, varscan2
- DYSF | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50556493; called by muse, mutect2
- DZIP3 | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV64313667; called by muse, mutect2, varscan2
- E2F1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58536112; called by muse, mutect2, varscan2
- ECEL1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV58814134; called by muse, mutect2, varscan2
- ECPAS | c.1511C>G p.S504* | Nonsense Mutation (SNP) | VAF 30/138 reads (22%) | catalogued as COSV52206466; called by muse, varscan2
- EEF2K | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.376); catalogued as COSV53786552; called by muse, mutect2, varscan2
- EFCAB3 | c.146T>A p.M49K | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV59504600; called by muse, mutect2, varscan2
- EGFLAM | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs746669041, COSV59298727; called by muse, mutect2, varscan2
- EGFLAM | c.2794A>C p.R932= (on ENST00000354891 / NM_001205301.2; = p.R924= on NM_152403.4) | Splice Region (SNP) | VAF 40/110 reads (36%) | catalogued as COSV59315681; called by muse, mutect2, varscan2
- EIF2AK3 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs1279792355, COSV57546267, COSV57551700; called by muse, mutect2, varscan2
- EIF2AK3 | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57551719; called by muse, mutect2, varscan2
- ELMO3 | c.320C>A p.A107E (on ENST00000652269; = p.A54E on NM_024712.5) | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs762228993, COSV62607660; called by muse, mutect2, varscan2
- ENPP1 | c.418T>A p.C140S | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62935846; called by muse, mutect2, varscan2
- EPB41L3 | c.530-2A>T p.X177_splice | Splice Site (SNP) | VAF 31/62 reads (50%) | catalogued as COSV59466282; called by muse, mutect2, varscan2
- EPHA8 | c.2165A>G p.D722G | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51293726; called by muse, mutect2, varscan2
- ERCC8 | c.669G>C p.L223F | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV54018040; called by muse, mutect2, varscan2
- ESR1 | c.975del p.I326Yfs*17 | Frame Shift Del (DEL) | VAF 54/156 reads (35%) | catalogued as rs1467954450, CM016108, COSV52782058; called by mutect2, pindel, varscan2
- ESRRG | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV63179043; called by muse, mutect2, varscan2
- ETNK1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV56889358; called by muse, mutect2, varscan2
- EVI2A | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.502); catalogued as COSV55986906; called by muse, mutect2, varscan2
- EYS | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV60998928; called by muse, mutect2, varscan2
- FAM181B | c.1197C>A p.Y399* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as COSV61301040; called by muse, mutect2, varscan2
- FAM184A | c.3349C>G p.Q1117E | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.979); catalogued as COSV58858323; called by muse, mutect2, varscan2
- FAM47A | c.2054C>G p.S685C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.79); catalogued as COSV60493918, COSV60499569; called by muse, mutect2, varscan2
- FAT2 | c.4669C>G p.Q1557E | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV55828497; called by muse, mutect2, varscan2
- FBN1 | c.7174C>T p.H2392Y | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57328801; called by muse, mutect2, varscan2
- FBXO32 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 124/234 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54892522; called by muse, mutect2, varscan2
- FBXW10 | c.426G>C p.Q142H | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100111112, COSV57321870; called by muse, mutect2, varscan2
- FGF8 | c.353G>A p.R118Q (on ENST00000344255 / NM_033164.4; = p.R100Q on NM_006119.6) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as rs769756528, COSV60143668; called by muse, mutect2, varscan2
- FIGN | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV60771418; called by muse, mutect2, varscan2
- FIGN | c.1258G>T p.G420W | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV60771424; called by muse, mutect2, varscan2
- FILIP1 | c.3343C>T p.H1115Y | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52739859; called by muse, mutect2, varscan2
- FLRT3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1433795820, COSV54047353; called by muse, mutect2, varscan2
- FN1 | c.4810C>A p.P1604T | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60562857; called by muse, mutect2, varscan2
- FN1 | c.1596C>G p.H532Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.94); catalogued as COSV60562872; called by muse, mutect2, varscan2
- FNDC1 | c.3527C>G p.S1176* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99796268; called by mutect2, varscan2
- FREM1 | c.3493G>C p.E1165Q | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as COSV66529547; called by muse, mutect2, varscan2
- FSCN2 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV58369148; called by muse, mutect2, varscan2
- FYB1 | c.2272G>T p.V758F (on ENST00000351578 / NM_199335.5; = p.V804F on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV60955482; called by muse, mutect2, varscan2
- GABRG1 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779053780, COSV54949711, COSV54954783; called by muse, mutect2, varscan2
- GATA3 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 107/147 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV60522140; called by muse, mutect2, varscan2
- GCC1 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58463678; called by muse, mutect2, varscan2
- GCC2 | c.3481G>T p.E1161* | Nonsense Mutation (SNP) | VAF 24/142 reads (17%) | catalogued as COSV59179620; called by muse, mutect2, varscan2
- GEMIN5 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as rs780724769, COSV53564351, COSV53566564; called by muse, mutect2, varscan2
- GJC2 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1357838753, COSV64513237; called by muse, mutect2, varscan2
- GLMN | c.1434G>C p.L478F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs925967829, COSV64861537; called by muse, mutect2
- GRIA2 | c.1641G>A p.W547* | Nonsense Mutation (SNP) | VAF 133/252 reads (53%) | catalogued as COSV52404146; called by muse, mutect2, varscan2
- GRIN2A | c.1516G>T p.V506F | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.875); catalogued as COSV58055153; called by muse, mutect2, varscan2
- GRIN2A | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as CM107222, COSV58055163; called by muse, mutect2, varscan2
- GRIP1 | c.1852del p.E618Nfs*9 (on ENST00000359742 / NM_001379345.1; = p.E566Nfs*9 on NM_021150.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/257 reads (15%) | catalogued as COSV99669920; called by mutect2, varscan2
- GSDMD | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52797774, COSV52798409; called by muse, mutect2, varscan2
- GTF3C4 | c.1527G>C p.Q509H | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64646031; called by muse, mutect2, varscan2
- GZF1 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV57636669; called by muse, mutect2, varscan2
- HADHB | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as CM031200, COSV58548455; called by muse, mutect2, varscan2
- HARS1 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56909112; called by muse, mutect2
- HBEGF | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 161/278 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50182659; called by muse, mutect2, varscan2
- HEATR1 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV63982882; called by muse, mutect2, varscan2
- HEATR4 | c.997C>A p.R333S | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as rs749894837, COSV58570586, COSV58577027; called by muse, mutect2, varscan2
- HECTD2 | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53219229, COSV53222895; called by muse, mutect2, varscan2
- HECW2 | c.3878T>C p.I1293T | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53672886; called by muse, mutect2, varscan2
- HFM1 | c.2146G>C p.V716L | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54036169; called by muse, mutect2, varscan2
- HIVEP2 | c.4291A>T p.S1431C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV50051755; called by muse, mutect2, varscan2
- HLF | c.451+2T>A p.X151_splice | Splice Site (SNP) | VAF 20/111 reads (18%) | catalogued as COSV56831821; called by muse, mutect2, varscan2
- HMCN1 | c.13776G>C p.W4592C | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54936803; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.274G>C p.E92Q (on ENST00000354667 / NM_031243.3; = p.E80Q on NM_002137.4) | Missense Mutation (SNP) | VAF 63/515 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV61161020; called by muse, mutect2, varscan2
- HOXB8 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53311454; called by muse, mutect2, varscan2
- HPSE2 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV65200510; called by muse, mutect2, varscan2
- HRNR | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 129/559 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV64262311; called by muse, mutect2, varscan2
- HS3ST5 | c.475T>C p.Y159H | Missense Mutation (SNP) | VAF 170/373 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57151101; called by muse, mutect2, varscan2
- HYAL3 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV60188005; called by muse, mutect2, varscan2
- IFNGR1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs387906572, COSV62990278; called by muse, mutect2
- IFNLR1 | c.860T>A p.V287E | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV59527544; called by muse, mutect2, varscan2
- IGHV1-45 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs367784343; called by muse, mutect2, varscan2
- INO80B | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.283); catalogued as rs1053183375, COSV51971504; called by muse, varscan2
- INPP5B | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774431618, COSV65958724; called by muse, mutect2, varscan2
- INTS11 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60090223; called by muse, mutect2, varscan2
- IREB2 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1307179648, COSV51926400, COSV99359236; called by muse, mutect2, varscan2
- ITGA4 | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV52003652; called by muse, mutect2, varscan2
- ITGA6 | c.1768G>C p.E590Q (on ENST00000442250; = p.E551Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV51255560; called by muse, mutect2, varscan2
- ITGB2 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as rs144806686; called by muse, mutect2, varscan2
- ITGBL1 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66011584, COSV66012915; called by muse, mutect2, varscan2
- ITLN1 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 111/155 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58276663; called by muse, mutect2, varscan2
- ITPR1 | c.5668G>C p.E1890Q (on ENST00000354582; = p.E1835Q on NM_002222.7) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV56977674; called by muse, mutect2, varscan2
- JPH1 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV60614384; called by muse, mutect2, varscan2
- KANSL1L | c.2683G>T p.D895Y | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV55996790; called by muse, mutect2, varscan2
- KATNIP | c.4361A>C p.D1454A | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190683; called by muse, mutect2, varscan2
- KCNH7 | c.3370G>A p.E1124K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV59811879; called by muse, mutect2, varscan2
- KIT | c.1654A>T p.M552L | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV55419418, COSV55429288; called by muse, mutect2, varscan2
- KMT2C | c.5254A>T p.K1752* | Nonsense Mutation (SNP) | VAF 124/192 reads (65%) | catalogued as COSV51496855; called by muse, mutect2, varscan2
- KMT2D | c.4160G>T p.G1387V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555195461, CM156342, COSV56464267, COSV56482157, COSV56500236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KNDC1 | c.507+1G>A p.X169_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV58845323; called by muse, mutect2, varscan2
- KPNB1 | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51600321; called by muse, mutect2, varscan2
- KRT10 | c.1751A>G p.Y584C | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV54091327; called by muse, mutect2, varscan2
- KSR2 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.138); catalogued as COSV60393419; called by muse, mutect2, varscan2
- LAMA2 | c.2284C>A p.H762N | Missense Mutation (SNP) | VAF 179/404 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70344808, COSV70354438; called by muse, mutect2, varscan2
- LAMC2 | c.1739C>G p.S580* | Nonsense Mutation (SNP) | VAF 83/131 reads (63%) | catalogued as COSV51459387; called by muse, mutect2, varscan2
- LARP4B | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 16/133 reads (12%) | catalogued as COSV60221422; called by muse, mutect2, varscan2
- LCOR | c.4271A>T p.H1424L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53718143; called by muse, mutect2, varscan2
- LCT | c.3892G>C p.E1298Q | Missense Mutation (SNP) | VAF 88/425 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51556762, COSV99930759; called by muse, mutect2, varscan2
- LHX2 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.731); catalogued as rs780990221, COSV65319058; called by muse, mutect2, varscan2
- LMO7 | c.3937G>T p.E1313* (on ENST00000357063; = p.E994* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV58547607; called by muse, mutect2, varscan2
- LRIF1 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.044); catalogued as COSV63898362; called by muse, mutect2, varscan2
- LRP1B | c.10765C>A p.P3589T | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.255); catalogued as COSV67238017; called by muse, mutect2, varscan2
- LRP2 | c.7599G>C p.E2533D | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV55571497; called by muse, mutect2, varscan2
- LRRC17 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV50867548; called by muse, mutect2, varscan2
- LRRC4C | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53436944; called by muse, mutect2, varscan2
- LRRC4C | c.889C>A p.H297N | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV53436953; called by muse, mutect2, varscan2
- LRRC7 | c.2710C>A p.P904T (on ENST00000651989 / NM_001370785.2; = p.P871T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50609637; called by muse, mutect2, varscan2
- LRRC7 | c.3244G>C p.A1082P (on ENST00000651989 / NM_001370785.2; = p.A1049P on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV50488071, COSV50609965; called by muse, mutect2, varscan2
- LRRIQ3 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as COSV63049390; called by muse, mutect2, varscan2
- LRRN4 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs745636377, COSV66646414; called by muse, mutect2, varscan2
- LRRTM3 | c.225A>C p.K75N | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV63671332; called by muse, mutect2, varscan2
- LRRTM4 | c.489C>G p.H163Q | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69141865; called by muse, mutect2, varscan2
- LTBP1 | c.1216C>G p.P406A (on ENST00000404816 / NM_206943.4; = p.P80A on NM_000627.4) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770495458, COSV63183872, COSV63197030; called by muse, mutect2, varscan2
- MACO1 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV65477772; called by muse, mutect2, varscan2
- MAF | c.1077C>G p.N359K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.714); catalogued as COSV58155199; called by muse, mutect2, varscan2
- MAGEB18 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 5/8 reads (63%) | catalogued as COSV57464965; called by muse, mutect2, varscan2
- MAGEE2 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64897991, COSV64898437; called by muse, mutect2, varscan2
- MAML2 | c.1046A>C p.Q349P | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV73262744, COSV73264658; called by muse, mutect2, varscan2
- MAN2C1 | c.2509A>T p.T837S | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV51241766; called by muse, mutect2, varscan2
- MAP1A | c.5628C>G p.F1876L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV55812163; called by muse, mutect2, varscan2
- MAP3K13 | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53996624; called by muse, mutect2, varscan2
- MAP3K19 | c.1559T>C p.I520T | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as COSV59641848; called by muse, mutect2, varscan2
- MAP4K4 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 23/128 reads (18%) | catalogued as rs866505635, COSV56339735; called by muse, mutect2, varscan2
- MARCHF1 | c.624C>G p.F208L (on ENST00000274056; = p.F191L on NM_017923.4) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.225); catalogued as COSV56830701; called by muse, mutect2, varscan2
- MARCKSL1 | c.303C>A p.S101R | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV61481859, COSV61482379; called by muse, mutect2, varscan2
- MATN3 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68100582; called by muse, mutect2, varscan2
- MBNL1 | c.299T>C p.M100T | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV56834679; called by muse, mutect2, varscan2
- MCM4 | c.2016G>C p.Q672H | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV50631859; called by muse, mutect2, varscan2
- MCOLN2 | c.799A>T p.S267C | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV52299328; called by muse, mutect2, varscan2
- MDC1 | c.5201C>T p.A1734V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV64526887, COSV64527268; called by muse, mutect2, varscan2
- MDN1 | c.15814A>G p.T5272A | Missense Mutation (SNP) | VAF 51/312 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV65529397; called by muse, mutect2, varscan2
- MKI67 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64076581; called by muse, mutect2, varscan2
- MMP16 | c.476G>C p.W159S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54187307; called by muse, mutect2, varscan2
- MMP20 | c.1224C>G p.F408L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV52777908; called by muse, mutect2, varscan2
- MORC1 | c.698C>A p.A233E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148630097, COSV51726582; called by muse, mutect2, varscan2
- MPEG1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs200053414, COSV57094601; called by muse, mutect2, varscan2
- MPEG1 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 130/215 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as COSV57094605; called by muse, mutect2, varscan2
- MPRIP | c.1106G>C p.R369T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59053808; called by muse, mutect2, varscan2
- MRE11 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV60577080; called by muse, mutect2
- MRM2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as rs1408176385, COSV54249086; called by muse, mutect2, varscan2
- MROH9 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs766660390, COSV63012034; called by muse, mutect2, varscan2
- MTHFD2 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV51202278; called by muse, mutect2, varscan2
- MTMR4 | c.1798C>A p.R600S | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.083); catalogued as COSV60203328; called by muse, mutect2, varscan2
- MTOR | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.66); catalogued as rs1180068151, COSV63875806; called by muse, mutect2, varscan2
- MTPAP | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV53935879; called by muse, mutect2, varscan2
- MUC17 | c.6517del p.V2173Wfs*20 | Frame Shift Del (DEL) | VAF 114/814 reads (14%) | catalogued as COSV100073764; called by mutect2, varscan2
- MYCBPAP | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.079); catalogued as COSV60411714; called by muse, mutect2, varscan2
- MYH1 | c.1929G>T p.K643N | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1233541338, COSV56845250, COSV56856418; called by muse, mutect2, varscan2
- MYH4 | c.3361G>T p.E1121* | Nonsense Mutation (SNP) | VAF 66/104 reads (63%) | catalogued as rs751412957, COSV55125261; called by muse, mutect2, varscan2
- MYT1L | c.2482A>G p.R828G | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV67731337; called by muse, mutect2, varscan2
- NAV3 | c.716C>A p.A239E | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs1439842289, COSV57109279; called by muse, mutect2, varscan2
- NBAS | c.5528C>T p.P1843L | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV55736355, COSV99866400; called by muse, mutect2, varscan2
- NCAPH | c.945C>G p.I315M | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs770262566, COSV53638405; called by muse, mutect2, varscan2
- NCKAP1 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV62943311; called by muse, mutect2, varscan2
- NCKAP1L | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV53211820; called by muse, mutect2, varscan2
- NCOR2 | c.3059G>A p.R1020Q | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs371445558; called by muse, mutect2, varscan2
- NDUFAF7 | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV50018743; called by muse, mutect2, varscan2
- NDUFS1 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.248); catalogued as rs746500004, COSV51913393; called by muse, mutect2, varscan2
- NEK10 | c.1752T>G p.H584Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58288883; called by muse, mutect2, varscan2
- NELL2 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100421306, COSV61575907; called by muse, mutect2, varscan2
- NEU4 | c.1412C>A p.P471H (on ENST00000391969 / NM_001167602.3; = p.P483H on NM_080741.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV57991858; called by muse, mutect2
- NEUROD1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs773337298, COSV54551014, COSV99716729; ClinVar: uncertain significance; called by muse, mutect2
- NFATC4 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 99/379 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.063); catalogued as rs756375882, COSV51610279; called by muse, mutect2, varscan2
- NLRP1 | c.4268C>A p.P1423H (on ENST00000572272 / NM_033004.4; = p.P1379H on NM_014922.5) | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV52574194, COSV52577558; called by muse, mutect2, varscan2
- NLRP14 | c.1993C>A p.L665I | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV55071640, COSV99079098; called by muse, mutect2, varscan2
- NLRP9 | c.1686G>A p.M562I | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as rs866482251, COSV60467365; called by muse, mutect2, varscan2
- NLRX1 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 74/135 reads (55%) | catalogued as COSV52709056; called by muse, mutect2, varscan2
- NOS1 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100499783, COSV57615053, COSV57620557; called by muse, mutect2
- NPAS4 | c.2039del p.P680Lfs*7 | Frame Shift Del (DEL) | VAF 66/287 reads (23%) | catalogued as COSV100214843; called by mutect2, pindel, varscan2
- NR0B1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV66764739; called by muse, mutect2
- NR1H2 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 42/51 reads (82%) | catalogued as COSV53802455; called by muse, mutect2, varscan2
- NRAP | c.3109C>T p.R1037* (on ENST00000359988 / NM_001322945.2; = p.R1002* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 26/107 reads (24%) | catalogued as rs868110215, COSV63489489; called by muse, mutect2, varscan2
- NRSN1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs199771455, COSV65893682, COSV65894498; called by muse, mutect2, varscan2
- NRXN1 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1197431819, COSV68002354, COSV68043995; called by muse, mutect2, varscan2
- NRXN2 | c.1768C>T p.H590Y | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55462223; called by muse, mutect2, varscan2
- NSD3 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs777597698, COSV57617110; called by muse, mutect2, varscan2
- NUDT19 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT tolerated (0.55); PolyPhen benign (0.073); catalogued as COSV67959865; called by muse, mutect2, varscan2
- NUP210L | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV55156670; called by muse, mutect2, varscan2
- NXN | c.363C>G p.L121= | Splice Region (SNP) | VAF 15/57 reads (26%) | catalogued as COSV61100585; called by muse, mutect2, varscan2
- NYAP2 | c.1842C>A p.S614R | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.663); catalogued as COSV56015547; called by muse, mutect2, varscan2
- OCA2 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as CM000191, COSV62348153, COSV62356906; called by muse, mutect2, varscan2
- OR10AG1 | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 92/168 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV56631934, COSV56634544; called by muse, mutect2, varscan2
- OR10G8 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV70908150, COSV70909378; called by muse, mutect2, varscan2
- OR13D1 | c.317C>G p.T106R | Missense Mutation (SNP) | VAF 216/520 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV59514944; called by muse, mutect2, varscan2
- OR1L3 | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 165/347 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV59170577; called by muse, mutect2, varscan2
- OR2M7 | c.188T>A p.L63H | Missense Mutation (SNP) | VAF 325/459 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58740535; called by muse, mutect2, varscan2
- OR2T12 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58779343; called by muse, mutect2, varscan2
- OR4C6 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV58606052; called by muse, mutect2, varscan2
- OR4K5 | c.958A>T p.T320S | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV60005110; called by muse, mutect2, varscan2
- OR5D16 | c.343A>T p.I115F | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65722750; called by muse, mutect2, varscan2
- OR5T2 | c.1044G>T p.Q348H | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57590777; called by muse, mutect2, varscan2
- OR6C4 | c.418A>T p.I140L | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as COSV67793264; called by muse, mutect2, varscan2
- OR8B4 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62070496; called by muse, mutect2
- OSBPL6 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV51929202; called by muse, mutect2, varscan2
- OTUD6B | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53444182; called by muse, mutect2, varscan2
- P2RX3 | c.581A>T p.N194I | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as COSV54444577; called by muse, mutect2, varscan2
- PAPPA | c.2833G>T p.G945W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60290828; called by muse, mutect2, varscan2
- PAPPA2 | c.1539C>A p.Y513* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV62785659; called by muse, mutect2, varscan2
- PAQR9 | c.948C>G p.I316M | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61419066; called by muse, mutect2, varscan2
- PARS2 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV64883940; called by muse, mutect2, varscan2
- PASK | c.723G>T p.W241C | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.196); catalogued as COSV52159632; called by muse, mutect2, varscan2
- PCDH11Y | c.1812C>A p.H604Q (on ENST00000400457 / NM_032973.2; = p.H593Q on NM_032971.3) | Missense Mutation (SNP) | VAF 84/115 reads (73%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); catalogued as COSV53090215; called by muse, mutect2, varscan2
- PCDH17 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769606349, COSV64974797; called by muse, mutect2, varscan2
- PCDHB12 | c.2074G>C p.V692L | Missense Mutation (SNP) | VAF 146/259 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV53400562; called by muse, mutect2, varscan2
- PCDHB5 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); catalogued as rs781948553, COSV50649434, COSV50667965; called by muse, mutect2, varscan2
- PCDHGA3 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV54021611, COSV99532296; called by muse, mutect2, varscan2
- PCLO | c.4318G>A p.E1440K | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765809782, COSV100432364, COSV61662532; called by muse, mutect2, varscan2
- PDCL | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52343459; called by muse, mutect2, varscan2
- PDK2 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV50304878; called by muse, mutect2, varscan2
- PDLIM4 | c.669C>T p.G223= | Splice Region (SNP) | VAF 26/47 reads (55%) | catalogued as COSV53805279; called by muse, mutect2, varscan2
- PDPR | c.1736C>G p.A579G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs370480421; called by mutect2, varscan2
- PDZD4 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV51250896; called by muse, mutect2, varscan2
- PDZRN3 | c.1008G>C p.L336F | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55214241; called by muse, mutect2, varscan2
- PDZRN4 | c.3013del p.D1005Tfs*4 (on ENST00000402685 / NM_001164595.2; = p.D747Tfs*4 on NM_013377.4) | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | catalogued as COSV100113469; called by mutect2, pindel, varscan2
- PFAS | c.1555G>C p.A519P | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58983032; called by muse, mutect2, varscan2
- PHEX | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65078499; called by muse, mutect2, varscan2
- PHKB | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54532718; called by muse, mutect2, varscan2
- PIK3CG | c.2022T>G p.D674E | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV63252898; called by muse, mutect2, varscan2
- PILRB | c.663G>T p.R221S | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV60336216; called by muse, mutect2, varscan2
- PIP5K1A | c.255G>C p.L85F (on ENST00000368888 / NM_001135638.2; = p.L72F on NM_003557.3) | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62959938; called by muse, mutect2, varscan2
- PKHD1 | c.12037G>C p.G4013R | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV64399187; called by muse, mutect2, varscan2
- PKHD1L1 | c.5513C>A p.P1838Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65751774; called by muse, mutect2, varscan2
- PKN2 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV65144439; called by muse, mutect2, varscan2
- PLD5 | c.669C>A p.F223L (on ENST00000442594; = p.F161L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV59146539, COSV59165956; called by muse, mutect2, varscan2
- PLEKHH2 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1452249965, COSV56752176; called by muse, mutect2, varscan2
- PLEKHM3 | c.23A>T p.D8V | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66818512; called by muse, mutect2, varscan2
- PLEKHO2 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs770541191, COSV60262855; called by muse, mutect2, varscan2
- PLSCR2 | c.391G>T p.A131S (on ENST00000497985 / NM_001199978.1; = p.A58S on NM_020359.2) | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV60864097; called by muse, mutect2, varscan2
- PNLIP | c.1048A>T p.S350C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV65041891; called by muse, mutect2, varscan2
- PNLIPRP3 | c.235del p.Q79Kfs*15 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as COSV65048786; called by mutect2, pindel, varscan2
- PNPLA7 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV52998476; called by muse, mutect2, varscan2
- PODXL2 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61066450; called by muse, mutect2, varscan2
- POGLUT1 | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55158298; called by muse, mutect2, varscan2
- POLA1 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs747452548, COSV66890399; called by muse, mutect2, varscan2
- POTEE | c.2419G>T p.E807* | Nonsense Mutation (SNP) | VAF 104/220 reads (47%) | catalogued as COSV58242817; called by muse, mutect2, varscan2
- PPP3CA | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV59930598; called by muse, mutect2, varscan2
- PRAG1 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV58166436; called by muse, mutect2, varscan2
- PRDM1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs753864501, COSV64850476; called by muse, mutect2, varscan2
- PREX2 | c.3420A>T p.S1140= | Splice Region (SNP) | VAF 16/143 reads (11%) | catalogued as COSV55796874; called by muse, mutect2, varscan2
- PRIMA1 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV60265493; called by muse, mutect2, varscan2
- PRLHR | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53303610, COSV53305030; called by muse, mutect2, varscan2
- PROS1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs772677117, COSV67776359; called by muse, mutect2, varscan2
- PRR5 | c.351G>T p.E117D (on ENST00000336985 / NM_181333.4; = p.E108D on NM_015366.4) | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.416); catalogued as COSV50063488, COSV99134457; called by muse, mutect2, varscan2
- PRSS1 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV61194810; called by muse, varscan2
- PRSS58 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs149180097, COSV73488438; called by muse, varscan2
- PRSS58 | c.275A>T p.H92L | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV73488845; called by muse, mutect2, varscan2
- PRUNE2 | c.7382G>C p.R2461P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs749929824, COSV65047130; called by muse, mutect2
- PSMB3 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs767214544; called by muse, mutect2, varscan2
- PSMD7 | c.689T>A p.L230Q | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54698578; called by muse, mutect2, varscan2
- PSME4 | c.3351G>C p.Q1117H | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV66367321; called by muse, mutect2, varscan2
- PTPRB | c.5248G>T p.D1750Y | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54252071, COSV99716597; called by muse, mutect2, varscan2
- PTPRO | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.135); catalogued as rs752919582, COSV55521537; called by muse, mutect2
- PXDN | c.2667G>A p.M889I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV53245387; called by muse, mutect2, varscan2
- PXK | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV57094116; called by muse, mutect2, varscan2
- QSOX2 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); catalogued as rs368303324; called by muse, mutect2, varscan2
- RABL6 | c.134A>T p.K45M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61040000; called by muse, mutect2, varscan2
- RAD23A | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as COSV100331019, COSV57135475; called by muse, mutect2
- RAET1L | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.058); catalogued as COSV53953966; called by muse, mutect2, varscan2
- RASGEF1A | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1230580317, COSV65667427; called by muse, mutect2, varscan2
- RASGRF1 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV69182894; called by muse, mutect2, varscan2
- RASGRP3 | c.1879G>T p.D627Y (on ENST00000402538 / NM_001349975.2; = p.D626Y on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as COSV67824840; called by muse, mutect2, varscan2
- RASGRP4 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs376854073, COSV53094097; called by muse, mutect2, varscan2
- RBBP8 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.243); catalogued as COSV59091564; called by muse, mutect2, varscan2
- RBMXL2 | c.1042C>A p.R348S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs774245349, COSV60978494, COSV60981517; called by muse, mutect2, varscan2
- RC3H2 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV59015029; called by muse, mutect2, varscan2
- REG1A | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52070456, COSV52071391; called by muse, mutect2, varscan2
- REG1B | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV59307652; called by muse, mutect2, varscan2
- REG3A | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59411670; called by muse, mutect2, varscan2
- RGS1 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV66506340; called by muse, mutect2, varscan2
- RGS3 | c.2142G>C p.Q714H (on ENST00000350696 / NM_001282923.2; = p.Q433H on NM_130795.4) | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV59521552; called by muse, mutect2, varscan2
- RIC1 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 358/427 reads (84%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.871); catalogued as COSV52613349; called by muse, mutect2, varscan2
- RIN3 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53654887, COSV99379115; called by muse, mutect2, varscan2
- RNASE13 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58795549; called by muse, mutect2, varscan2
- RND3 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 58/351 reads (17%) | catalogued as COSV55725867; called by muse, mutect2, varscan2
- RNF111 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs771024059, COSV62089388; called by muse, mutect2, varscan2
- RNF213 | c.1936C>T p.H646Y | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60629765; called by muse, mutect2, varscan2
- ROS1 | c.2548C>G p.Q850E | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV63861129; called by muse, mutect2, varscan2
- RP9 | c.471A>G p.I157M | Missense Mutation (SNP) | VAF 99/123 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV51807650; called by muse, mutect2, varscan2
- RXFP3 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV57507995; called by muse, mutect2, varscan2
- RYR2 | c.4478G>A p.S1493N | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as COSV63710720; called by muse, mutect2, varscan2
- SALL3 | c.3557G>T p.G1186V | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73306502; called by muse, mutect2, varscan2
- SAMD4A | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV51887523; called by muse, mutect2, varscan2
- SARDH | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.025); catalogued as COSV64107297; called by muse, mutect2, varscan2
- SARM1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.588); catalogued as COSV50229777; called by muse, mutect2, varscan2
- SBF1 | c.2791C>T p.L931F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62370204; called by muse, mutect2, varscan2
- SBF2 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 140/227 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139730490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBSPON | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52077917; called by muse, mutect2, varscan2
- SCEL | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 75/123 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV62994489; called by muse, mutect2, varscan2
- SCN10A | c.2397T>A p.F799L | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV71862584; called by muse, mutect2, varscan2
- SDCCAG8 | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV59416825; called by muse, mutect2, varscan2
- SEC24D | c.2642C>G p.S881C | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54876881, COSV54884346; called by muse, mutect2
- SEL1L2 | c.1777A>T p.N593Y | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53157549; called by muse, mutect2, varscan2
- SENP2 | c.1731G>C p.K577N | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56197513; called by muse, mutect2, varscan2
- SETX | c.6383C>G p.S2128C | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56393707; called by muse, mutect2, varscan2
- SETX | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56393720; called by muse, mutect2, varscan2
- SF3B1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as COSV59217658, COSV59226150; called by muse, mutect2, varscan2
- SGCB | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 85/138 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV67341482; called by muse, mutect2, varscan2
- SH2D7 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs762928222, COSV51949981; called by muse, mutect2, varscan2
- SH3BP4 | c.1851C>G p.I617M | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60644232, COSV60646175; called by muse, mutect2, varscan2
- SHOX2 | c.407C>T p.T136I (on ENST00000441443 / NM_006884.3; = p.T160I on NM_003030.4) | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV67464669; called by muse, mutect2, varscan2
- SHPRH | c.3704G>A p.R1235K (on ENST00000275233 / NM_001042683.3; = p.R1239K on NM_173082.3) | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as rs748596189, COSV51616832; called by muse, mutect2, varscan2
- SI | c.4582G>T p.A1528S | Missense Mutation (SNP) | VAF 124/239 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs747607478, COSV52298821; called by muse, mutect2, varscan2
- SI | c.1841G>C p.W614S | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52298837; called by muse, mutect2
- SI | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD1413632, COSV52298851; called by muse, mutect2
- SIK3 | c.2855C>T p.T952I (on ENST00000445177 / NM_001366686.2; = p.T910I on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.185); catalogued as COSV52622553; called by muse, mutect2, varscan2
- SIRPA | c.1507A>T p.R503W | Missense Mutation (SNP) | VAF 106/166 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61541400; called by muse, mutect2, varscan2
- SKIL | c.989A>T p.H330L | Missense Mutation (SNP) | VAF 56/382 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); catalogued as COSV52062769; called by muse, mutect2, varscan2
- SLC17A8 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV60126405; called by muse, mutect2, varscan2
- SLC23A1 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV62297523; called by muse, mutect2, varscan2
- SLC30A8 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV69975719; called by muse, mutect2, varscan2
- SLC30A8 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV69969419, COSV69969771; called by muse, mutect2, varscan2
- SLC35F4 | c.530C>T p.S177F (on ENST00000339762 / NM_001352015.2; = p.S141F on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60266920; called by muse, mutect2, varscan2
- SLC35G5 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55315025; called by muse, mutect2, varscan2
- SLC5A12 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54824469; called by muse, mutect2, varscan2
- SLC6A1 | c.1408T>A p.S470T | Missense Mutation (SNP) | VAF 113/205 reads (55%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV55118490; called by muse, mutect2, varscan2
- SLC6A5 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs1187593242, COSV54231668; called by muse, mutect2, varscan2
- SLCO1C1 | c.218G>T p.R73M | Missense Mutation (SNP) | VAF 141/293 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56871656, COSV56876914; called by muse, mutect2, varscan2
- SLCO1C1 | c.1453A>C p.T485P | Missense Mutation (SNP) | VAF 118/174 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.435); catalogued as COSV56879141; called by muse, varscan2
- SLCO4C1 | c.966G>C p.W322C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1207033626, COSV60517833, COSV60519832; called by muse, mutect2, varscan2
- SLIT1 | c.2807A>G p.N936S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1338252828, COSV56597983; called by muse, mutect2
- SLITRK3 | c.2276G>T p.R759L | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV53852766, COSV53852922; called by muse, mutect2, varscan2
- SLITRK5 | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV61525865; called by muse, mutect2, varscan2
- SMARCA1 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64410923, COSV64413608; called by muse, mutect2, varscan2
- SMC1B | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1156594952, COSV62533065; called by muse, mutect2, varscan2
- SNAP91 | c.632A>T p.Y211F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52133140; called by muse, mutect2, varscan2
- SNTG2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.363); catalogued as COSV57985380; called by muse, mutect2, varscan2
- SORCS2 | c.2710A>G p.T904A | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.387); catalogued as rs1297433075, COSV61182200; called by muse, mutect2, varscan2
- SORCS3 | c.2993A>G p.E998G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV63798283; called by muse, mutect2
- SOX14 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60163370; called by muse, mutect2, varscan2
- SPAG17 | c.6533-1C>T p.X2178_splice | Splice Site (SNP) | VAF 44/183 reads (24%) | catalogued as COSV60467465; called by muse, mutect2, varscan2
- SPATA31D1 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV61200765; called by muse, mutect2, varscan2
- SPATA31E1 | c.562A>T p.S188C | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV57794886; called by muse, mutect2, varscan2
- SPATS1 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 87/151 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55824794; called by muse, mutect2, varscan2
- SPHKAP | c.3411G>A p.M1137I | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60892555; called by muse, mutect2, varscan2
- SPHKAP | c.889C>A p.Q297K | Missense Mutation (SNP) | VAF 92/463 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60892565; called by muse, mutect2, varscan2
- SPTA1 | c.5403G>T p.W1801C | Missense Mutation (SNP) | VAF 123/187 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754553, COSV63758563; called by muse, mutect2, varscan2
- SPTA1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs933454103, COSV63758566; called by muse, mutect2, varscan2
- SRRM2 | c.4526G>A p.C1509Y | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV57079897; called by muse, mutect2, varscan2
- SRRT | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52343097; called by muse, mutect2, varscan2
- STAG2 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 63/84 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1320089945, COSV54371304; called by muse, mutect2, varscan2
- STAG3 | c.3050C>A p.P1017H | Missense Mutation (SNP) | VAF 202/648 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV57934541; called by muse, mutect2, varscan2
- STAT5B | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53182032, COSV99511132; called by mutect2, varscan2
- STK36 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs138126812; called by muse, mutect2, varscan2
- STRIP2 | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772928723, COSV50807830; called by muse, mutect2, varscan2
- SUGT1 | c.948C>G p.I316M (on ENST00000343788 / NM_001130912.3; = p.I284M on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59423730; called by muse, mutect2, varscan2
- SUPT16H | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV53527460; called by muse, mutect2
- SYCP2L | c.1169A>T p.Q390L | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51657150; called by muse, mutect2, varscan2
- SYNE1 | c.17845A>C p.N5949H (on ENST00000367255 / NM_182961.4; = p.N5878H on NM_033071.3) | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55088042; called by muse, mutect2, varscan2
- SYNE2 | c.3589G>T p.D1197Y | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV59967922; called by muse, mutect2, varscan2
- SYNE2 | c.8891G>A p.R2964H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs769752828, COSV59948760; called by muse, mutect2, varscan2
- SYT4 | c.679G>T p.G227W | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54902398; called by muse, mutect2, varscan2
- TAAR1 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV51589385; called by muse, mutect2, varscan2
- TAF1C | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs377368073; called by muse, mutect2, varscan2
- TAF1L | c.3403C>G p.Q1135E | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV54261735, COSV54264219; called by muse, mutect2, varscan2
- TAS1R3 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59565424; called by muse, mutect2, varscan2
- TAS1R3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs745746390, COSV59563358; called by muse, mutect2, varscan2
- TAS2R1 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV66779392; called by muse, mutect2, varscan2
- TBC1D10C | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as rs779615548, COSV56705089; called by mutect2, varscan2
- TBC1D19 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV53521168; called by muse, mutect2, varscan2
- TBC1D22B | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65143379; called by muse, mutect2, varscan2
- TCL1A | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV68086167; called by muse, mutect2, varscan2
- TCTN2 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as COSV57633518, COSV57634699; called by muse, mutect2, varscan2
- TET2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV54431147; called by muse, mutect2, varscan2
- TGFBR3 | c.1368T>A p.C456* | Nonsense Mutation (SNP) | VAF 38/164 reads (23%) | catalogued as COSV53030694; called by muse, mutect2, varscan2
- THNSL2 | c.1203C>A p.Y401* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV59084594; called by muse, mutect2, varscan2
- THRB | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54982208; called by muse, mutect2, varscan2
- THUMPD1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67263513; called by muse, mutect2, varscan2
- TIAM1 | c.2296C>G p.P766A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV54572316, COSV54579282; called by muse, mutect2, varscan2
- TMEM116 | c.188A>C p.H63P | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV61393910; called by muse, mutect2, varscan2
- TMEM132E | c.1045C>T p.Q349* (on ENST00000321639; = p.Q439* on NM_001304438.2) | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100396509, COSV58700235; called by muse, mutect2, varscan2
- TMPRSS15 | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.113); catalogued as COSV53048149; called by muse, mutect2, varscan2
- TNFRSF10A | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55325479; called by muse, mutect2, varscan2
- TNK2 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV57370530, COSV57375259; called by muse, mutect2
- TPST1 | c.1031A>C p.E344A | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV59180274; called by muse, mutect2, varscan2
- TRAPPC9 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV101227893, COSV66908899; called by muse, mutect2, varscan2
- TRHDE | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV53863877; called by muse, mutect2, varscan2
- TRIM15 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.927); catalogued as COSV64990335; called by muse, mutect2, varscan2
- TRIM44 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1183381193, COSV54987237; called by muse, mutect2, varscan2
- TRIM50 | c.677A>T p.E226V | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV60795805; called by muse, mutect2, varscan2
- TRPA1 | c.1129A>T p.N377Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100084705; called by muse, mutect2, varscan2
- TRPA1 | c.994-1G>T p.X332_splice | Splice Site (SNP) | VAF 44/131 reads (34%) | catalogued as COSV51559807; called by muse, mutect2, varscan2
- TRPC3 | c.1090C>G p.L364V (on ENST00000379645 / NM_001366479.2; = p.L291V on NM_003305.2) | Missense Mutation (SNP) | VAF 84/145 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53380599, COSV53382311; called by muse, mutect2, varscan2
- TSHZ1 | c.2098G>T p.G700W (on ENST00000580243 / NM_001308210.2; = p.G655W on NM_005786.6) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV59016266; called by muse, mutect2, varscan2
- TSPYL2 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 27/48 reads (56%) | catalogued as COSV64921472; called by muse, mutect2, varscan2
- TTC39B | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 87/102 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52616187; called by muse, mutect2, varscan2
- TTN | c.95615C>T p.A31872V (on ENST00000591111; = p.A24448V on NM_003319.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | PolyPhen probably damaging (0.939); catalogued as COSV60309878; called by muse, mutect2, varscan2
- TTN | c.94634G>A p.S31545N (on ENST00000591111; = p.S24121N on NM_003319.4) | Missense Mutation (SNP) | VAF 18/91 reads (20%) | PolyPhen benign (0.177); catalogued as COSV60309907; called by muse, mutect2, varscan2
- TTN | c.62894C>A p.T20965K (on ENST00000591111; = p.T13541K on NM_003319.4) | Missense Mutation (SNP) | VAF 88/212 reads (42%) | PolyPhen probably damaging (0.997); catalogued as COSV60309992; called by muse, mutect2, varscan2
- TTN | c.62285C>A p.T20762K (on ENST00000591111; = p.T13338K on NM_003319.4) | Missense Mutation (SNP) | VAF 69/256 reads (27%) | PolyPhen benign (0.165); catalogued as COSV60310028; called by muse, mutect2, varscan2
- TTN | c.44152G>C p.D14718H (on ENST00000591111; = p.D7294H on NM_003319.4) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | PolyPhen probably damaging (0.999); catalogued as COSV60310062; called by muse, mutect2, varscan2
- TUT4 | c.3290A>G p.Y1097C | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57119256; called by muse, mutect2, varscan2
- UBL7 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 58/154 reads (38%) | catalogued as COSV63706697; called by muse, mutect2, varscan2
- UBR3 | c.3535A>G p.K1179E | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55859253; called by muse, mutect2, varscan2
- UFL1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV65150638; called by muse, mutect2, varscan2
- UGT2B28 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 76/133 reads (57%) | catalogued as rs765142835, COSV59434165; called by muse, mutect2, varscan2
- UNC5B | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs751544453, COSV58980992; called by muse, mutect2, varscan2
- UQCRFS1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs141991079; called by muse, mutect2
- USH2A | c.5755G>A p.G1919S | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56353212; called by muse, mutect2, varscan2
- VPREB3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV50707610; called by muse, mutect2, varscan2
- VPS13D | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs752053638, COSV62531376; called by muse, mutect2, varscan2
- VWA3B | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68246330; called by muse, varscan2
- VWA3B | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 40/232 reads (17%) | catalogued as COSV68246333; called by muse, varscan2
- VWA3B | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV68246336; called by muse, mutect2, varscan2
- WDR11 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54792679; called by muse, mutect2, varscan2
- WDR11 | c.3194-1G>A p.X1065_splice | Splice Site (SNP) | VAF 38/118 reads (32%) | catalogued as rs750535769, COSV54792690; called by muse, mutect2, varscan2
- WDR59 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV50943532; called by muse, mutect2, varscan2
- WDR72 | c.2179C>A p.L727M | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV64753295; called by muse, mutect2, varscan2
- WDR86 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57843285; called by muse, mutect2, varscan2
- WDR86 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV57843307; called by muse, mutect2, varscan2
- WDR91 | c.1805C>G p.A602G | Missense Mutation (SNP) | VAF 72/372 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV60371682; called by muse, mutect2, varscan2
- WIZ | c.5344G>T p.D1782Y (on ENST00000673675 / NM_001371589.1; = p.D687Y on NM_021241.3) | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54612052; called by muse, mutect2, varscan2
- WWC3 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.927); catalogued as COSV66506957; called by muse, mutect2, varscan2
- XPO1 | c.130A>G p.R44G | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV68947571; called by muse, mutect2, varscan2
- XPO4 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as COSV55004511, COSV99689259; called by muse, mutect2, varscan2
- YIPF4 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as rs776659336, COSV53213704; called by muse, mutect2, varscan2
- ZBBX | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 58/536 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV100284205, COSV56792438, COSV56800194; called by muse, mutect2, varscan2
- ZC3H14 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51773207; called by muse, mutect2, varscan2
- ZEB2 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV57965389; called by muse, mutect2, varscan2
- ZFHX4 | c.9761C>A p.P3254Q | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV51493118; called by muse, mutect2, varscan2
- ZFP28 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV56737794; called by muse, mutect2, varscan2
- ZFPM2 | c.3347C>A p.T1116N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV65875619; called by muse, mutect2, varscan2
- ZFY | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV50083890; called by muse, mutect2, varscan2
- ZIC1 | c.96C>A p.D32E | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV51550662, COSV51556170; called by muse, mutect2, varscan2
- ZNF107 | c.863A>T p.N288I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.117); catalogued as COSV61331655; called by muse, mutect2, varscan2
- ZNF257 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 65/173 reads (38%) | catalogued as COSV71311493; called by muse, mutect2, varscan2
- ZNF257 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV71311500; called by mutect2, varscan2
- ZNF345 | c.1054A>C p.S352R | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.584); catalogued as COSV59325166; called by muse, mutect2, varscan2
- ZNF385B | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV61181237; called by muse, mutect2, varscan2
- ZNF391 | c.552G>C p.Q184H | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV55124567; called by muse, mutect2, varscan2
- ZNF415 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV54704682; called by muse, mutect2, varscan2
- ZNF417 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as rs1568528485, COSV56309852; called by muse, mutect2, varscan2
- ZNF429 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV61918777; called by muse, mutect2, varscan2
- ZNF431 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as COSV60675222; called by muse, mutect2, varscan2
- ZNF440 | c.1043A>G p.D348G | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58372384; called by muse, mutect2, varscan2
- ZNF500 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | catalogued as COSV54788422; called by muse, mutect2, varscan2
- ZNF500 | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV54789850; called by muse, mutect2, varscan2
- ZNF501 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV68516293, COSV68516658; called by muse, mutect2, varscan2
- ZNF536 | c.3184G>T p.D1062Y | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as COSV62821061; called by muse, mutect2
- ZNF599 | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 102/288 reads (35%) | catalogued as COSV61397361; called by muse, mutect2, varscan2
- ZNF676 | c.1018C>A p.P340T (on ENST00000650058; = p.P308T on NM_001001411.3) | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV68094754; called by muse, varscan2
- ZNF684 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65519651; called by muse, mutect2, varscan2
- ZNF804A | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV56469075; called by muse, mutect2, varscan2
- ZNF93 | c.380C>A p.T127K | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59378204; called by muse, mutect2, varscan2
- ZRANB1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV62843976; called by muse, mutect2, varscan2
- ZSCAN25 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 169/417 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV53554448; called by muse, mutect2, varscan2
- ANK1 | c.4428dup p.G1477Wfs*67 | Frame Shift Ins (INS) | VAF 82/222 reads (37%) | called by mutect2, pindel, varscan2
- FARP2 | c.1769dup p.H590Qfs*52 | Frame Shift Ins (INS) | VAF 13/105 reads (12%) | called by pindel, varscan2
- FBXL8 | c.860A>T p.D287V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- FRG2 | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- IGHG4 | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 88/364 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-16 | c.199G>C p.V67L | Missense Mutation (SNP) | VAF 195/516 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- IGKV1D-13 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- MAPT | c.1017del p.I340Sfs*25 (on ENST00000262410 / NM_001377265.1; = p.I265Sfs*25 on NM_016835.4) | Frame Shift Del (DEL) | VAF 33/84 reads (39%) | called by mutect2, pindel, varscan2
- MRC1 | c.1526A>G p.K509R | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- MYLK | c.2706del p.K903Rfs*3 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | called by mutect2, pindel, varscan2
- OR2D3 | c.252dup p.A85Cfs*8 | Frame Shift Ins (INS) | VAF 50/178 reads (28%) | called by mutect2, pindel, varscan2
- OR4C6 | c.831_832del p.P278Hfs*? | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by pindel, varscan2
- OVOL2 | c.380del p.G127Afs*8 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by pindel, varscan2
- RGS6 | c.883del p.E295Nfs*5 | Frame Shift Del (DEL) | VAF 53/236 reads (22%) | called by mutect2, pindel, varscan2
- SLC38A10 | c.2272del p.V758Cfs*76 | Frame Shift Del (DEL) | VAF 89/254 reads (35%) | called by mutect2, pindel, varscan2
- SLCO1C1 | c.1462del p.E488Nfs*50 | Frame Shift Del (DEL) | VAF 107/221 reads (48%) | called by pindel, varscan2
- STARD10 | c.107_108del p.E36Vfs*2 | Frame Shift Del (DEL) | VAF 43/181 reads (24%) | called by pindel, varscan2
- TOX3 | c.366del p.V123Wfs*30 | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | called by mutect2, pindel, varscan2
- TPR | c.3557_3558del p.L1186Qfs*2 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by pindel, varscan2
- TPTE | c.914A>T p.D305V (on ENST00000618007 / NM_199261.4; = p.D287V on NM_199259.4) | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- UNC5C | c.1425del p.N476Tfs*2 | Frame Shift Del (DEL) | VAF 165/372 reads (44%) | called by mutect2, pindel, varscan2
- VENTX | c.271dup p.A91Gfs*174 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- ZNF605 | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- ABCA3 | c.4996C>T p.L1666= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV57059270; called by muse, mutect2, varscan2
- ABCA3 | c.1713G>A p.G571= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV57059281; called by muse, mutect2, varscan2
- ABCB5 | c.1596G>A p.R532= (on ENST00000404938 / NM_001163941.2; = p.R87= on NM_178559.6) | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV51717317, COSV51719822; called by muse, mutect2, varscan2
- ACOT9 | c.1017A>G p.A339= | Silent (SNP) | VAF 49/86 reads (57%) | catalogued as COSV60538828; called by muse, mutect2, varscan2
- ADGRL3 | c.1545A>G p.T515= (on ENST00000506720 / NM_001322402.2; = p.T447= on NM_015236.6) | Silent (SNP) | VAF 68/122 reads (56%) | catalogued as rs746930203, COSV72231817; called by muse, mutect2, varscan2
- ADPRS | c.861C>T p.C287= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV52882053; called by muse, mutect2, varscan2
- AGO2 | c.1560C>G p.V520= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV55052331; called by muse, mutect2, varscan2
- AGPAT4 | c.600C>G p.L200= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV57250537; called by muse, mutect2, varscan2
- AHSG | c.276G>T p.L92= | Silent (SNP) | VAF 128/186 reads (69%) | catalogued as COSV56609225; called by muse, mutect2, varscan2
- ANKIB1 | c.2502C>T p.A834= | Silent (SNP) | VAF 161/425 reads (38%) | catalogued as COSV56065638; called by muse, mutect2, varscan2
- AP1B1 | c.1335G>T p.R445= | Silent (SNP) | VAF 34/172 reads (20%) | catalogued as COSV58023071; called by muse, varscan2
- AP3B1 | c.2760G>A p.G920= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV54891943; called by muse, mutect2, varscan2
- APC2 | c.5199C>G p.P1733= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV52021770; called by muse, mutect2, varscan2
- APOB | c.2991G>A p.G997= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs868815351, COSV51950408; called by muse, mutect2, varscan2
- ARHGAP11A | c.1326G>T p.G442= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1238258569, COSV64381592; called by muse, mutect2, varscan2
- ARHGAP33 | c.1155G>T p.V385= | Silent (SNP) | VAF 88/115 reads (77%) | catalogued as COSV50156262; called by muse, mutect2, varscan2
- ATP2A1 | c.2406C>G p.L802= | Silent (SNP) | VAF 53/204 reads (26%) | catalogued as COSV100707127, COSV62870816; called by muse, mutect2, varscan2
- ATRNL1 | c.2985C>A p.T995= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV58112457; called by muse, mutect2, varscan2
- BARX2 | c.825C>A p.P275= | Silent (SNP) | VAF 40/67 reads (60%) | catalogued as COSV55651891, COSV55652249; called by muse, mutect2, varscan2
- BEX4 | c.174T>C p.L58= | Silent (SNP) | VAF 26/37 reads (70%) | catalogued as COSV65516214; called by muse, mutect2, varscan2
- BRINP3 | c.1728C>T p.F576= | Silent (SNP) | VAF 146/202 reads (72%) | catalogued as rs1369875350, COSV66527447; called by muse, mutect2, varscan2
- C1orf127 | c.1875A>G p.P625= | Silent (SNP) | VAF 40/137 reads (29%) | catalogued as rs150211489; called by muse, mutect2, varscan2
- C4BPA | c.612C>T p.D204= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as rs757593380, COSV65536181, COSV65536865; called by muse, mutect2, varscan2
- C6 | c.879C>A p.I293= | Silent (SNP) | VAF 67/218 reads (31%) | catalogued as COSV54709963, COSV54717415; called by muse, mutect2, varscan2
- CAPN6 | c.1662C>A p.V554= | Silent (SNP) | VAF 58/104 reads (56%) | catalogued as COSV60696986; called by muse, mutect2, varscan2
- CARD16 | c.423T>C p.S141= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as COSV65213427; called by muse, mutect2, varscan2
- CC2D1A | c.996C>A p.P332= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV58786024; called by muse, mutect2, varscan2
- CCDC181 | c.1047G>A p.K349= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV63157946; called by muse, mutect2, varscan2
- CCDC50 | c.159G>A p.Q53= | Silent (SNP) | VAF 64/640 reads (10%) | catalogued as COSV66669536; called by muse, mutect2
- CD163 | c.1989T>C p.P663= | Silent (SNP) | VAF 64/114 reads (56%) | catalogued as COSV63136752; called by muse, mutect2, varscan2
- CFAP20DC | c.1413G>A p.Q471= (on ENST00000482387 / NM_001351530.2; = p.Q346= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV55926669; called by muse, mutect2, varscan2
- CFAP91 | c.1941A>G p.L647= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs777888852, COSV56344361; called by muse, mutect2, varscan2
- CHTF8 | c.192C>T p.I64= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs1567588739, COSV54709045; called by muse, mutect2, varscan2
- COL1A2 | c.924C>T p.A308= | Silent (SNP) | VAF 22/207 reads (11%) | catalogued as COSV51957194; called by muse, mutect2, varscan2
- COMP | c.1248G>A p.P416= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs368715216; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRACDL | c.726G>A p.R242= | Silent (SNP) | VAF 104/284 reads (37%) | catalogued as COSV67409999; called by muse, mutect2, varscan2
- CSMD2 | c.9231C>A p.S3077= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53956803, COSV53963479; called by muse, mutect2, varscan2
- CSMD3 | c.1731C>T p.V577= (on ENST00000297405 / NM_001363185.1; = p.V473= on NM_052900.3) | Silent (SNP) | VAF 43/206 reads (21%) | catalogued as COSV52303619, COSV99826109; called by muse, mutect2, varscan2
- CTAGE6 | c.762C>T p.H254= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs1229403497, COSV69917186; called by mutect2, varscan2
- CTNNA3 | c.1848A>G p.T616= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs182490263, COSV65615279, COSV65616366; called by muse, mutect2, varscan2
- CTNND2 | c.1128G>T p.S376= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV58909935, COSV58923755; called by muse, mutect2, varscan2
- CUL9 | c.1923G>T p.L641= | Silent (SNP) | VAF 35/53 reads (66%) | catalogued as COSV52734051; called by muse, mutect2, varscan2
- DDX17 | c.558G>A p.L186= | Silent (SNP) | VAF 18/205 reads (9%) | catalogued as COSV53256155; called by muse, mutect2, varscan2
- DENND5A | c.2913C>T p.F971= | Silent (SNP) | VAF 42/480 reads (9%) | catalogued as rs773130783, COSV60231294; called by muse, mutect2
- DISP2 | c.1914C>A p.P638= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV51141102; called by muse, mutect2
- DNAH3 | c.8808C>G p.L2936= | Silent (SNP) | VAF 107/457 reads (23%) | catalogued as COSV54548164; called by muse, mutect2, varscan2
- DNER | c.1293G>T p.V431= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV59163446, COSV59175353; called by muse, mutect2, varscan2
- DOK3 | c.975C>T p.Y325= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs199711375; called by muse, mutect2, varscan2
- DPF2 | c.66G>A p.E22= | Silent (SNP) | VAF 71/256 reads (28%) | catalogued as COSV52891212; called by muse, mutect2, varscan2
- DPPA2 | c.723G>T p.L241= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV72118303; called by muse, mutect2, varscan2
- DPY19L3 | c.1728G>C p.A576= | Silent (SNP) | VAF 93/126 reads (74%) | catalogued as COSV60479793; called by muse, mutect2, varscan2
- DPYSL4 | c.189G>T p.L63= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV58309725; called by muse, mutect2, varscan2
- DSTN | c.120C>T p.L40= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV55714230, COSV99855268; called by muse, mutect2, varscan2
- EPHA1 | c.858G>A p.R286= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV51975968; called by muse, mutect2, varscan2
- EPHB1 | c.1329C>G p.V443= | Silent (SNP) | VAF 44/305 reads (14%) | catalogued as COSV67670279; called by muse, mutect2, varscan2
- EPHB2 | c.3150C>T p.D1050= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV65866244; called by muse, mutect2
- ERBB4 | c.1333C>T p.L445= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as rs767472865, COSV53581973; called by muse, mutect2, varscan2
- ESRRG | c.273G>T p.L91= | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as COSV63157384; called by mutect2, varscan2
- EXO1 | c.1008A>G p.E336= | Silent (SNP) | VAF 71/111 reads (64%) | catalogued as COSV62219543; called by muse, mutect2, varscan2
- EXOC4 | c.1773G>A p.L591= | Silent (SNP) | VAF 11/299 reads (4%) | catalogued as COSV54120259; called by muse, mutect2
- EYS | c.1737T>A p.A579= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV60998917; called by muse, mutect2, varscan2
- F2RL3 | c.1089C>G p.T363= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV50186504; called by muse, mutect2, varscan2
- FAM135B | c.1005C>T p.L335= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV52750853; called by muse, mutect2, varscan2
- FAM13C | c.153A>T p.A51= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV53255196; called by muse, mutect2, varscan2
- FAP | c.474T>G p.V158= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV51867054; called by muse, mutect2, varscan2
- FARP2 | c.2034G>T p.L678= | Silent (SNP) | VAF 50/101 reads (50%) | catalogued as COSV50880024; called by muse, mutect2, varscan2
- FAT4 | c.9189A>G p.A3063= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV58706119; called by muse, mutect2, varscan2
- FBN1 | c.2403T>C p.D801= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV57328810; called by muse, mutect2, varscan2
- FBXL13 | c.447G>A p.E149= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV100501746, COSV57543740; called by muse, mutect2, varscan2
- FFAR3 | c.87C>A p.L29= | Silent (SNP) | VAF 32/214 reads (15%) | catalogued as COSV59909196, COSV59909320; called by muse, mutect2, varscan2
- FGF10 | c.162C>A p.S54= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV52939197; called by muse, mutect2, varscan2
- FPGT | c.531T>A p.V177= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV63846134; called by muse, mutect2, varscan2
- FRG2C | c.654G>T p.L218= | Silent (SNP) | VAF 31/185 reads (17%) | called by muse, mutect2, varscan2
- FTHL17 | c.300C>A p.A100= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV63267329; called by muse, mutect2, varscan2
- GALNT13 | c.1338C>T p.G446= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV101223035, COSV67237071; called by muse, mutect2, varscan2
- GALNT5 | c.1845A>G p.P615= | Silent (SNP) | VAF 86/225 reads (38%) | catalogued as COSV52040864; called by muse, mutect2, varscan2
- GAPVD1 | c.3828C>T p.T1276= (on ENST00000394104; = p.T1285= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs376087686, COSV99782643; called by muse, mutect2, varscan2
- GAS2L1 | c.720G>C p.S240= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs200625190, COSV53331500; called by muse, mutect2, varscan2
- GCM2 | c.1041C>T p.N347= | Silent (SNP) | VAF 114/174 reads (66%) | catalogued as rs1248548904, COSV101069628, COSV65276452; called by muse, mutect2, varscan2
- GDA | c.186G>C p.P62= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV52997154; called by muse, mutect2, varscan2
- GLDN | c.1284T>C p.A428= | Silent (SNP) | VAF 109/284 reads (38%) | catalogued as COSV59092213; called by muse, mutect2, varscan2
- GLI1 | c.1503C>T p.L501= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV57360653, COSV57366719; called by muse, mutect2, varscan2
- GPR148 | c.240G>A p.L80= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV59309356; called by muse, mutect2, varscan2
- GYPA | c.282C>G p.L94= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as COSV51636694; called by muse, mutect2, varscan2
- HDAC4 | c.2916C>T p.L972= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs200479723; called by muse, mutect2, varscan2
- HECTD4 | c.6684G>A p.L2228= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV66399052; called by muse, mutect2, varscan2
- HECTD4 | c.5967G>A p.V1989= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV66399057; called by muse, mutect2, varscan2
- HMCN1 | c.7407C>T p.I2469= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs940310147, COSV54932730; called by muse, mutect2, varscan2
- HNRNPU | c.114C>G p.L38= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV51693907; called by muse, mutect2, varscan2
- HSF5 | c.528G>C p.A176= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV60203313; called by muse, mutect2, varscan2
- HTR1A | c.237G>A p.A79= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1372481454, COSV60500412, COSV60502793; called by muse, mutect2
- HTR3A | c.870C>T p.I290= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs766993465, COSV55471294; called by muse, mutect2, varscan2
- IGHV1-45 | c.333C>T p.A111= | Silent (SNP) | VAF 108/376 reads (29%) | catalogued as rs782533277; called by muse, mutect2, varscan2
- IGHV1-46 | c.57C>G p.S19= | Silent (SNP) | VAF 32/168 reads (19%) | catalogued as rs1555524875; called by muse, mutect2, varscan2
- IPO13 | c.1932C>T p.L644= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV64894988; called by muse, mutect2, varscan2
- IQGAP1 | c.4683G>T p.L1561= | Silent (SNP) | VAF 65/195 reads (33%) | catalogued as COSV51590822; called by muse, mutect2, varscan2
- IRAK2 | c.1866C>G p.L622= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs369701928; called by muse, mutect2, varscan2
- KCNK9 | c.987C>A p.S329= | Silent (SNP) | VAF 41/156 reads (26%) | catalogued as COSV57287778, COSV57289015; called by muse, mutect2, varscan2
- KCNMA1 | c.837G>A p.L279= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV54282916; called by muse, mutect2, varscan2
- KCNT2 | c.3123G>A p.L1041= | Silent (SNP) | VAF 109/151 reads (72%) | catalogued as COSV54106146; called by muse, mutect2, varscan2
- KCNU1 | c.1815C>T p.V605= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV67759497; called by muse, mutect2, varscan2
- KDR | c.2830C>A p.R944= | Silent (SNP) | VAF 60/91 reads (66%) | catalogued as COSV55766825, COSV55768653; called by muse, mutect2, varscan2
- KIAA1549L | c.2457G>T p.L819= (on ENST00000321505; = p.L1116= on NM_012194.3) | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV55780319; called by muse, mutect2, varscan2
- KIF1A | c.2949G>T p.L983= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV57500480; called by muse, mutect2, varscan2
- KIF1B | c.4374G>A p.Q1458= (on ENST00000377086 / NM_001365952.1; = p.Q1412= on NM_015074.3) | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV55815367; called by muse, mutect2, varscan2
- KLF12 | c.942G>C p.R314= | Silent (SNP) | VAF 69/108 reads (64%) | catalogued as COSV66581045; called by muse, mutect2, varscan2
- KMT2A | c.9387C>G p.L3129= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as COSV63292059; called by muse, mutect2
- KRT12 | c.840C>G p.G280= | Silent (SNP) | VAF 48/82 reads (59%) | catalogued as COSV52432316; called by muse, mutect2, varscan2
- KRT82 | c.783C>T p.I261= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs1309250119, COSV99233765; called by mutect2, varscan2
- LAP3 | c.147G>T p.V49= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV56901564; called by muse, mutect2, varscan2
- LGR5 | c.261C>A p.P87= | Silent (SNP) | VAF 78/472 reads (17%) | catalogued as COSV99878185; called by mutect2, varscan2
- LHCGR | c.732C>A p.S244= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as rs1297774831, COSV54293226, COSV54302385; called by muse, mutect2, varscan2
- LHFPL5 | c.591C>T p.F197= | Silent (SNP) | VAF 35/52 reads (67%) | catalogued as rs781007782, COSV64178664; called by muse, mutect2, varscan2
- LRCH3 | c.1266G>A p.K422= | Silent (SNP) | VAF 118/215 reads (55%) | catalogued as COSV58396269; called by muse, mutect2, varscan2
- LRFN5 | c.1725G>T p.G575= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV53272959, COSV99985432; called by muse, mutect2, varscan2
- LRRC30 | c.279G>C p.L93= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV67301338, COSV67302245; called by muse, mutect2, varscan2
- LRRC71 | c.1575C>T p.F525= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs769631994, COSV59358246; called by muse, mutect2, varscan2
- LYZL2 | c.57C>T p.S19= | Silent (SNP) | VAF 78/109 reads (72%) | catalogued as rs140215273; called by muse, varscan2
- MAGEL2 | c.2106A>T p.A702= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV58568948; called by muse, mutect2, varscan2
- MAP3K19 | c.1869A>G p.T623= | Silent (SNP) | VAF 134/471 reads (28%) | catalogued as COSV59641841; called by muse, mutect2, varscan2
- MARCHF10 | c.1872C>T p.F624= | Silent (SNP) | VAF 52/275 reads (19%) | catalogued as COSV60886244; called by muse, mutect2, varscan2
- MEPCE | c.1569C>T p.F523= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as COSV52769936; called by muse, mutect2, varscan2
- MKRN3 | c.330G>A p.K110= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV58811951; called by muse, mutect2, varscan2
- MPP3 | c.918G>A p.P306= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs770195012, COSV68199157; called by muse, mutect2, varscan2
- MRGPRD | c.669C>T p.V223= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV58423174, COSV58424060; called by muse, mutect2, varscan2
- MUC16 | c.30549A>T p.P10183= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV67490137; called by muse, mutect2, varscan2
- NAV1 | c.2208G>T p.R736= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV55225370; called by muse, mutect2, varscan2
- NCAPG2 | c.1431A>C p.V477= | Silent (SNP) | VAF 50/220 reads (23%) | catalogued as COSV51991314; called by muse, mutect2, varscan2
- NEIL3 | c.675A>T p.I225= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV52813302, COSV52813765; called by muse, mutect2, varscan2
126 further variants in this file (0 protein-altering or splice-affecting, 104 silent, 22 other) are not listed here.
